Somatic mutation profile of tumor specimen C3L-00640-01 (aliquot CPT0064520010) from CPTAC case C3L-00640, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.3 years (21,667 days).
Specimen C3L-00640-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccc4ebee-4a09-47dd-81cd-be7447116057.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00640-31 (Blood Derived Normal), aliquot CPT0066660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5bcead2-3ba4-4a0e-9595-fb74fa1604de

The open-access MAF lists 44 somatic variants for this specimen: 25 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 15, 3'Flank 2, Intron 1, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 20/294 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 30/360 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CAMK1D | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1160339552, COSV101123382, COSV66618326; called by muse, mutect2
- CLIC3 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV65406421; called by muse, mutect2, varscan2
- COL18A1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs899510965; called by muse, mutect2, varscan2
- GRIN3B | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760582633; called by muse, mutect2, varscan2
- ISM2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754380719, COSV53636434; called by muse, mutect2, varscan2
- KCNB2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV73050758; called by muse, varscan2
- KCNK3 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs1185578898, COSV57191531; called by muse, mutect2
- MYO10 | c.3928G>A p.A1310T | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs751350671; called by muse, mutect2, varscan2
- OR5AP2 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756963104, COSV57257858; called by muse, mutect2
- RBM5 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as rs1559698584, COSV61737053; called by muse, mutect2
- SCUBE2 | c.2620C>T p.R874C (on ENST00000649792 / NM_001367977.2; = p.R817C on NM_020974.3) | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289340109, COSV58548458; called by muse, mutect2, varscan2
- SYP | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs782810430, COSV54295798; called by muse, mutect2, varscan2
- ZNF536 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs905189576, COSV62819778; called by muse, mutect2
- ABCA1 | c.1250A>T p.E417V | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- CALML5 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FAM71C | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 45/436 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- HNRNPF | c.748A>C p.S250R | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2
- KCNQ3 | c.1915del p.L639Sfs*42 | Frame Shift Del (DEL) | VAF 24/310 reads (8%) | called by mutect2, pindel
- PLXNA2 | c.2596G>T p.V866L | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- SLIRP | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SMAD4 | c.1075_1076dup p.D360Efs*25 | Frame Shift Ins (INS) | VAF 16/126 reads (13%) | called by mutect2, pindel
- SOX30 | c.1523T>C p.L508P | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF385D | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ACACA | c.2763A>C p.R921= | Silent (SNP) | VAF 16/183 reads (9%) | called by muse, mutect2
- ADGRG2 | c.2034C>A p.V678= (on ENST00000379869 / NM_001079858.3; = p.V675= on NM_005756.4) | Silent (SNP) | VAF 21/259 reads (8%) | called by muse, mutect2
- C1orf105 | c.489A>T p.L163= | Silent (SNP) | VAF 15/202 reads (7%) | called by muse, mutect2
- COL6A3 | c.5112C>T p.D1704= | Silent (SNP) | VAF 42/515 reads (8%) | catalogued as rs759756382, COSV55080190; ClinVar: likely benign; called by muse, mutect2
- EYS | c.5823T>C p.N1941= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- IL36RN | c.84T>C p.A28= | Silent (SNP) | VAF 40/482 reads (8%) | called by muse, mutect2
- MAP1A | c.6096C>T p.T2032= | Silent (SNP) | VAF 35/346 reads (10%) | called by muse, mutect2, varscan2
- PLEKHF1 | c.90G>A p.A30= | Silent (SNP) | VAF 20/163 reads (12%) | called by mutect2, varscan2
- S1PR5 | c.471G>A p.A157= | Silent (SNP) | VAF 23/212 reads (11%) | called by muse, mutect2, varscan2
- SLC6A3 | c.1305C>T p.I435= | Silent (SNP) | VAF 61/451 reads (14%) | catalogued as rs760545154; called by muse, mutect2, varscan2
- TCTEX1D4 | c.61C>A p.R21= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100221267; called by muse, mutect2
- THRAP3 | c.876G>A p.G292= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as rs768748683; called by muse, mutect2, varscan2
- TPSG1 | c.138C>T p.A46= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as rs779284702; called by muse, mutect2, varscan2
- TSPAN14 | c.726C>T p.A242= | Silent (SNP) | VAF 19/228 reads (8%) | called by muse, mutect2
- ZNF423 | c.3120G>A p.T1040= (on ENST00000563137 / NM_001379286.1; = p.T1032= on NM_015069.4) | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs145829157, COSV52189873; called by muse, mutect2
- H2BP2 | chr1:143876264 C>T | 3'Flank (SNP) | VAF 25/774 reads (3%) | called by muse, mutect2
- MAML3 | c.468+18647C>T | Intron (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- TRIM73 | chr7:75410208 C>A | 3'Flank (SNP) | VAF 4/262 reads (2%) | called by muse, mutect2
- VAPB | c.*359G>A | 3'UTR (SNP) | VAF 34/315 reads (11%) | catalogued as rs562368880; called by muse, mutect2, varscan2
